Somatic mutation profile of tumor specimen TCGA-B5-A11R-01A (aliquot TCGA-B5-A11R-01A-11D-A122-09) from TCGA case TCGA-B5-A11R, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 51.7 years (18,878 days).
Specimen TCGA-B5-A11R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a01723a3-d5f2-4285-af10-63601420eb4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11R-10A (Blood Derived Normal), aliquot TCGA-B5-A11R-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c9e48c5-e7f9-45d3-bfe1-4a45a2a9472e

The open-access MAF lists 724 somatic variants for this specimen: 539 protein-altering or splice-affecting, 174 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 473, Silent 174, Nonsense Mutation 47, Splice Site 8, Splice Region 5, Intron 4, 3'UTR 3, Frame Shift Del 3, RNA 2, Frame Shift Ins 2, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 58/222 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1057519891, COSV57247504, COSV57260861, COSV57263527; ClinVar: likely pathogenic; called by muse, varscan2
- ERBB3 | c.890A>T p.D297V | Missense Mutation (SNP) | VAF 59/220 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057519892, COSV57258897, COSV57260882; ClinVar: likely pathogenic; called by muse, varscan2
- NFE2L2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 99/244 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 119/216 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV55904673; called by muse, mutect2, varscan2
- PIK3CA | c.3132T>A p.N1044K | Missense Mutation (SNP) | VAF 19/317 reads (6%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen possibly damaging (0.63); catalogued as COSV55875087, COSV55897116; called by muse, mutect2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 126/455 reads (28%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1027-1G>T p.X343_splice | Splice Site (SNP) | VAF 116/223 reads (52%) | hotspot (GDC flag); catalogued as CS1413088, COSV64290834, COSV64293694, COSV64298429; called by muse, mutect2, varscan2
- ABCA8 | c.1184C>G p.S395* | Nonsense Mutation (SNP) | VAF 59/181 reads (33%) | catalogued as COSV52209668; called by muse, mutect2, varscan2
- ABCB11 | c.1999G>C p.E667Q | Missense Mutation (SNP) | VAF 138/330 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV55595187; called by muse, mutect2, varscan2
- ABCC10 | c.652G>A p.E218K (on ENST00000372530 / NM_001198934.2; = p.E175K on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.549); catalogued as COSV55092751; called by muse, mutect2, varscan2
- ABCC3 | c.3776G>A p.R1259K | Missense Mutation (SNP) | VAF 67/159 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53327514; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV68344524; called by muse, mutect2, varscan2
- ACADVL | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as COSV50034954, COSV50038813; called by muse, mutect2, varscan2
- ACIN1 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 92/248 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as rs749042086, COSV52980818; called by muse, varscan2
- ACSM6 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 120/422 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.18); catalogued as COSV58980039; called by muse, varscan2
- ADAMTSL3 | c.3747G>C p.Q1249H | Missense Mutation (SNP) | VAF 105/252 reads (42%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.924); catalogued as COSV54464475, COSV54465122; called by muse, mutect2, varscan2
- ADCY4 | c.3198G>C p.L1066F | Missense Mutation (SNP) | VAF 91/242 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV60256830; called by muse, mutect2, varscan2
- ADGRL2 | c.3305C>T p.S1102L (on ENST00000370717 / NM_001366005.1; = p.S1089L on NM_012302.4) | Missense Mutation (SNP) | VAF 106/262 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs1262524010, COSV54683733; called by muse, mutect2, varscan2
- ADH1C | c.1094C>G p.S365C | Missense Mutation (SNP) | VAF 105/272 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV72624944; called by muse, mutect2, varscan2
- ADPRH | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs150984649, COSV63695504; called by muse, mutect2, varscan2
- AGGF1 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as rs1020092262, COSV57230850; called by muse, mutect2, varscan2
- AGGF1 | c.1202-1G>C p.X401_splice | Splice Site (SNP) | VAF 15/316 reads (5%) | catalogued as COSV100461910; called by muse, mutect2
- AHI1 | c.1761G>A p.W587* | Nonsense Mutation (SNP) | VAF 93/492 reads (19%) | catalogued as COSV55634167; called by muse, mutect2, varscan2
- AHNAK | c.14848G>C p.E4950Q | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.98); catalogued as COSV57226333; called by muse, mutect2, varscan2
- AIM2 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 89/317 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV63701503; called by muse, mutect2, varscan2
- AKAP9 | c.6430G>C p.E2144Q (on ENST00000359028; = p.E2112Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62355365; called by muse, mutect2, varscan2
- ALPK2 | c.6461C>T p.S2154F | Missense Mutation (SNP) | VAF 204/483 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1348146324, COSV64496073; called by muse, mutect2, varscan2
- ALS2 | c.3092C>T p.S1031L | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV51891589; called by muse, mutect2, varscan2
- AMIGO3 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs750202189, COSV57539853; called by muse, mutect2, varscan2
- AMOTL1 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV58569606; called by muse, mutect2, varscan2
- ANK3 | c.986C>G p.S329* | Nonsense Mutation (SNP) | VAF 152/299 reads (51%) | catalogued as COSV55051004, COSV55076756; called by muse, mutect2, varscan2
- ANKAR | c.1318A>C p.I440L | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.978); catalogued as COSV55616828; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 85/232 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51856055; called by muse, mutect2, varscan2
- ANKRD26 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 401/772 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.237); catalogued as COSV65777495; called by muse, mutect2, varscan2
- ANKRD6 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 87/145 reads (60%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV60235591; called by muse, mutect2, varscan2
- ANPEP | c.2776G>C p.E926Q | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.026); catalogued as rs1567152296, COSV55594019; called by muse, mutect2, varscan2
- AP1G1 | c.2078C>G p.S693* | Nonsense Mutation (SNP) | VAF 58/144 reads (40%) | catalogued as COSV55494061; called by muse, mutect2, varscan2
- AP3B1 | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54890953; called by muse, mutect2, varscan2
- APC | c.5638G>A p.E1880K | Missense Mutation (SNP) | VAF 147/375 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.396); catalogued as COSV57372382; called by muse, mutect2, varscan2
- APLNR | c.191C>A p.A64D | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV57243778; called by muse, mutect2, varscan2
- APMAP | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV54176483, COSV54176642; called by muse, mutect2, varscan2
- ARHGAP6 | c.219G>C p.E73D | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs1230588546, COSV61633996; called by muse, mutect2, varscan2
- ARID1A | c.1897C>T p.Q633* | Nonsense Mutation (SNP) | VAF 77/173 reads (45%) | catalogued as COSV61375026; called by muse, mutect2, varscan2
- ASPM | c.3010C>T p.Q1004* | Nonsense Mutation (SNP) | VAF 151/678 reads (22%) | catalogued as rs919745643, COSV54136538; called by muse, mutect2, varscan2
- ASPM | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 73/432 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as COSV54136551; called by muse, mutect2, varscan2
- ASTN1 | c.2093C>T p.S698F | Missense Mutation (SNP) | VAF 76/155 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV56071449, COSV56081198; called by muse, mutect2, varscan2
- ASXL3 | c.5083G>A p.A1695T | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV52455952; called by muse, mutect2, varscan2
- ATF1 | c.647G>C p.R216T | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV50395594; called by muse, mutect2, varscan2
- ATP1A2 | c.1412G>A p.R471K | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV63405500; called by muse, mutect2, varscan2
- ATP8A2 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 91/283 reads (32%) | catalogued as COSV54942822; called by muse, mutect2, varscan2
- ATP9B | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56959077; called by muse, mutect2, varscan2
- ATR | c.3148G>C p.E1050Q | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as COSV63390678; called by muse, mutect2, varscan2
- ATXN1 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV55228036; called by muse, mutect2, varscan2
- BARHL2 | c.774C>A p.S258R | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64981880; called by muse, mutect2, varscan2
- BBOF1 | c.787C>G p.Q263E | Missense Mutation (SNP) | VAF 140/334 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV67455526; called by muse, mutect2, varscan2
- BCL7A | c.574G>A p.V192M (on ENST00000261822 / NM_001024808.3; = p.V213M on NM_020993.5) | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs949794860, COSV99947042; called by muse, mutect2
- BLOC1S5 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 362/638 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV55242708; called by muse, mutect2, varscan2
- BMP1 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.724); catalogued as COSV60482755; called by muse, mutect2, varscan2
- BMP5 | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 332/562 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs751006049, COSV63705726; called by muse, mutect2, varscan2
- BRCA2 | c.7463G>C p.R2488T | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM107509, COSV66460546; called by muse, mutect2, varscan2
- BRCC3 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 152/408 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.37); catalogued as rs868965023, COSV57462045, COSV57463879; called by muse, mutect2, varscan2
- BTK | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 157/420 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100437984, COSV58122965; called by muse, mutect2, varscan2
- C10orf120 | c.741C>G p.F247L | Missense Mutation (SNP) | VAF 176/492 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61492157, COSV61492416, COSV61492519; called by muse, mutect2, varscan2
- C10orf71 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs527554528, COSV60505463; called by muse, mutect2, varscan2
- C10orf88 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 106/440 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.787); catalogued as COSV64404303; called by muse, mutect2, varscan2
- C1orf100 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 74/372 reads (20%) | catalogued as rs760285735, COSV57372652; called by muse, mutect2, varscan2
- C1orf43 | c.268G>A p.E90K (on ENST00000368521 / NM_001297718.2; = p.E56K on NM_015449.4) | Missense Mutation (SNP) | VAF 104/465 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV62966749; called by muse, mutect2, varscan2
- C9orf85 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 127/292 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.867); catalogued as COSV58255703; called by muse, varscan2
- C9orf85 | c.200C>G p.P67R | Missense Mutation (SNP) | VAF 134/328 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100594989, COSV58255721; called by muse, varscan2
- CACHD1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 170/375 reads (45%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.968); catalogued as rs756542793, COSV51558766; called by muse, mutect2, varscan2
- CACNA1F | c.5734G>C p.A1912P | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV59906454; called by muse, mutect2, varscan2
- CACNA2D2 | c.2245G>A p.D749N (on ENST00000479441 / NM_001174051.3; = p.D742N on NM_006030.4) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV56568052; called by muse, mutect2, varscan2
- CANX | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as rs553234403, COSV56005032; called by muse, mutect2, varscan2
- CARD11 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV67801714; called by muse, mutect2, varscan2
- CASK | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 37/320 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as COSV59373651; called by muse, mutect2, varscan2
- CATSPERB | c.1081C>G p.L361V | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV56424106, COSV56432713; called by muse, mutect2, varscan2
- CBLL2 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 107/256 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.169); catalogued as COSV60370021; called by muse, mutect2, varscan2
- CC2D2A | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 103/301 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.075); catalogued as COSV67505306; called by muse, mutect2, varscan2
- CCDC180 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs768434399, COSV63830653, COSV63831225; called by muse, mutect2, varscan2
- CCDC38 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 95/307 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60184453; called by muse, mutect2, varscan2
- CCDC58 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.287); catalogued as COSV51659358; called by muse, mutect2, varscan2
- CCDC96 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.258); catalogued as COSV100027954; called by muse, mutect2
- CD4 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 78/129 reads (60%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV50590440; called by muse, mutect2, varscan2
- CDC42BPA | c.4997C>T p.S1666L (on ENST00000334218 / NM_001366019.2; = p.S1653L on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV100504273, COSV62018241; called by muse, mutect2, varscan2
- CDH11 | c.1402C>T p.Q468* | Nonsense Mutation (SNP) | VAF 53/135 reads (39%) | catalogued as COSV51773705; called by muse, mutect2, varscan2
- CDK12 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 155/323 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs771063488, COSV71002430; called by muse, mutect2, varscan2
- CENPF | c.8124G>C p.K2708N | Missense Mutation (SNP) | VAF 69/369 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV100871470, COSV65278286; called by muse, mutect2, varscan2
- CENPK | c.438G>C p.L146F | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV54469314; called by muse, mutect2, varscan2
- CEP170 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 151/731 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV60505947; called by muse, mutect2, varscan2
- CERS4 | c.993G>A p.M331I | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV52169926; called by muse, mutect2, varscan2
- CES4A | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV58657829; called by muse, mutect2, varscan2
- CFAP43 | c.1715G>A p.G572E | Missense Mutation (SNP) | VAF 147/284 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53380580; called by muse, mutect2, varscan2
- CFAP65 | c.2311G>C p.E771Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.857); catalogued as COSV58565445; called by muse, mutect2, varscan2
- CFAP69 | c.2536G>A p.A846T | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs1260822682, COSV100290157; called by muse, mutect2
- CHID1 | c.342G>C p.K114N | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as COSV60260224; called by muse, mutect2, varscan2
- CHRM2 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57772164; called by muse, mutect2, varscan2
- CHRNA6 | c.830C>G p.S277* | Nonsense Mutation (SNP) | VAF 74/240 reads (31%) | catalogued as rs747826040, COSV52380554, COSV99373250; called by muse, mutect2
- CHRNA6 | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 109/361 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52379129, COSV99373252; called by muse, mutect2, varscan2
- CHSY1 | c.773G>A p.C258Y | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99573928; called by muse, mutect2
- CLCN6 | c.1799G>A p.R600K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs147364570; called by muse, mutect2, varscan2
- CLEC17A | c.546C>G p.F182L | Missense Mutation (SNP) | VAF 103/295 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60429254; called by muse, mutect2, varscan2
- CLUH | c.1091C>T p.T364M (on ENST00000435359; = p.T402M on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1392153994, COSV70929826; called by muse, mutect2, varscan2
- CNTNAP4 | c.2836G>A p.E946K | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV100271880, COSV56676821; called by muse, mutect2, varscan2
- COL18A1 | c.2837C>T p.P946L (on ENST00000359759 / NM_130444.3; = p.P711L on NM_030582.4) | Missense Mutation (SNP) | VAF 4/6 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62702692; called by mutect2, varscan2
- COL3A1 | c.1798G>C p.G600R | Missense Mutation (SNP) | VAF 97/265 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58594981; called by muse, mutect2, varscan2
- COL5A1 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs777376620, COSV65673514; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPAMD8 | c.1019C>T p.S340F (on ENST00000651564; = p.S293F on NM_015692.5) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV52238666; called by muse, mutect2, varscan2
- CPNE1 | c.394C>T p.Q132* (on ENST00000352393; = p.Q137* on NM_003915.5) | Nonsense Mutation (SNP) | VAF 100/241 reads (41%) | catalogued as COSV58294234; called by muse, mutect2, varscan2
- CRY1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 136/548 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs773978446, COSV99150826; called by muse, mutect2
- CSPG5 | c.414C>G p.I138M | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV53132997; called by muse, mutect2, varscan2
- CTCF | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 52/130 reads (40%) | catalogued as COSV50466874; called by muse, mutect2, varscan2
- CYP4F2 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.566); catalogued as COSV50002385; called by muse, mutect2, varscan2
- CYP7A1 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV100052412; called by muse, mutect2
- DAAM2 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0.309); catalogued as COSV51411624; called by muse, mutect2, varscan2
- DCAF6 | c.1849G>A p.E617K (on ENST00000312263 / NM_001349778.1; = p.E637K on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.075); catalogued as COSV56583750; called by muse, mutect2, varscan2
- DDX24 | c.23C>G p.S8* | Nonsense Mutation (SNP) | VAF 102/260 reads (39%) | catalogued as COSV58213512; called by muse, mutect2, varscan2
- DDX3X | c.639C>G p.I213M (on ENST00000399959; = p.I214M on NM_001356.5) | Missense Mutation (SNP) | VAF 117/274 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67864350; called by muse, varscan2
- DDX60L | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV52720081; called by muse, varscan2
- DENND2B | c.2354C>G p.P785R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV58206966; called by muse, mutect2, varscan2
- DENND4C | c.2614A>G p.S872G | Missense Mutation (SNP) | VAF 86/193 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV66823127; called by muse, mutect2, varscan2
- DEPDC5 | c.2891C>G p.S964C (on ENST00000400246; = p.S1033C on NM_014662.5) | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56706440, COSV56707493; called by muse, mutect2, varscan2
- DGAT2L6 | c.319C>G p.H107D | Missense Mutation (SNP) | VAF 141/362 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60718488; called by muse, mutect2, varscan2
- DHX15 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 114/276 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61028869; called by muse, mutect2, varscan2
- DHX57 | c.512C>G p.S171* | Nonsense Mutation (SNP) | VAF 63/156 reads (40%) | catalogued as COSV54890012; called by muse, varscan2
- DHX57 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV54890026; called by muse, varscan2
- DISP3 | c.973C>G p.L325V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV53835330; called by muse, mutect2, varscan2
- DMKN | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as rs746196142, COSV60088708; called by muse, mutect2, varscan2
- DNAJA2 | c.699C>G p.F233L | Missense Mutation (SNP) | VAF 149/370 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57694919, COSV57695366; called by muse, mutect2, varscan2
- DNER | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs991151351, COSV59173961; called by muse, mutect2, varscan2
- DOCK11 | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 98/248 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52245955; called by muse, mutect2, varscan2
- DOCK8 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 142/330 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV66635509; called by muse, mutect2, varscan2
- DPEP1 | c.1228C>G p.L410V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as COSV55361620; called by muse, mutect2, varscan2
- DPP3 | c.1668C>G p.F556L | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.199); catalogued as COSV64757732; called by muse, mutect2, varscan2
- DPYD | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV60082653; called by muse, mutect2, varscan2
- DSP | c.5402C>G p.S1801* | Nonsense Mutation (SNP) | VAF 185/310 reads (60%) | catalogued as COSV65794953; called by muse, mutect2, varscan2
- EDC4 | c.3485G>A p.R1162Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as rs1291528620, COSV59303609; called by muse, mutect2, varscan2
- EED | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 158/371 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as COSV54557869; called by muse, mutect2, varscan2
- EFCAB5 | c.3145G>A p.D1049N | Missense Mutation (SNP) | VAF 130/313 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427516066, COSV57935410; called by muse, mutect2, varscan2
- EFL1 | c.31C>G p.Q11E | Missense Mutation (SNP) | VAF 178/446 reads (40%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV51604507, COSV51609077; called by muse, mutect2, varscan2
- EGFLAM | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 72/193 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.81); catalogued as COSV59314042; called by muse, mutect2, varscan2
- EHBP1 | c.679C>G p.Q227E | Missense Mutation (SNP) | VAF 94/240 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV50432111; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1970G>C p.R657T | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57517729; called by muse, mutect2, varscan2
- ELL | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV53215280; called by muse, mutect2, varscan2
- ELMO1 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.216); catalogued as COSV60319872; called by muse, mutect2, varscan2
- EMILIN2 | c.1876C>T p.Q626* | Nonsense Mutation (SNP) | VAF 48/141 reads (34%) | catalogued as COSV54421730; called by muse, mutect2, varscan2
- ENTR1 | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.379); catalogued as rs951114639, COSV53742864; called by muse, mutect2, varscan2
- EPHA10 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.52); PolyPhen benign (0.058); catalogued as rs771803475, COSV60402406; called by muse, mutect2, varscan2
- EZR | c.989G>C p.R330T | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV61455697; called by muse, mutect2, varscan2
- F8 | c.1658C>G p.S553C | Missense Mutation (SNP) | VAF 176/418 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as CM083682, COSV64269402; called by muse, mutect2, varscan2
- FAF2 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs780444729, COSV56132741; called by muse, mutect2, varscan2
- FAM120C | c.918G>A p.M306I | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV60261820; called by muse, mutect2, varscan2
- FAM177A1 | c.557C>T p.S186L (on ENST00000382406 / NM_001289022.2; = p.S209L on NM_173607.5) | Missense Mutation (SNP) | VAF 81/237 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV54834639; called by muse, mutect2, varscan2
- FAM234B | c.1621G>A p.G541S | Missense Mutation (SNP) | VAF 75/253 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.27); catalogued as rs747104306, COSV52196792, COSV99545582; called by muse, mutect2, varscan2
- FASLG | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 130/287 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV60680809; called by muse, mutect2, varscan2
- FAT1 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 110/255 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV71671761, COSV71675565; called by muse, mutect2, varscan2
- FCF1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs771901257, COSV100115891, COSV58696863; called by muse, mutect2, varscan2
- FCMR | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV65569214; called by muse, mutect2, varscan2
- FGD1 | c.1088A>T p.Q363L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as COSV64309446; called by muse, mutect2, varscan2
- FGD2 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1172770308, COSV51465572; called by muse, mutect2, varscan2
- FHL1 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs1360899812, COSV61782460; called by muse, mutect2, varscan2
- FILIP1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 98/177 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52738557; called by muse, mutect2, varscan2
- FLNA | c.4330G>A p.D1444N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs1557177410, COSV61049363; called by muse, mutect2, varscan2
- FNTB | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.254); catalogued as COSV55763677; called by muse, mutect2, varscan2
- FZD4 | c.1600G>C p.E534Q | Missense Mutation (SNP) | VAF 103/256 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.514); catalogued as COSV72294651; called by muse, mutect2, varscan2
- GAB4 | c.1697C>G p.S566* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV68754939; called by muse, mutect2, varscan2
- GABRA1 | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 116/290 reads (40%) | catalogued as COSV50101153, COSV50115545; called by muse, mutect2, varscan2
- GABRQ | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs868914661, COSV64783605; called by muse, mutect2, varscan2
- GALNT5 | c.1904G>C p.R635T | Missense Mutation (SNP) | VAF 211/484 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52040444; called by muse, mutect2, varscan2
- GAPT | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59247291; called by muse, mutect2, varscan2
- GARNL3 | c.1428dup p.E477Rfs*11 | Frame Shift Ins (INS) | VAF 87/294 reads (30%) | catalogued as rs763344646; called by mutect2, pindel, varscan2
- GNAO1 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.85); PolyPhen benign (0.149); catalogued as rs956210011, COSV52616076; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPATCH3 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 85/218 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV64652562; called by muse, mutect2, varscan2
- GPHN | c.405C>G p.I135M | Missense Mutation (SNP) | VAF 263/627 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59490469; called by muse, mutect2, varscan2
- GPR17 | c.328C>G p.L110V | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.832); catalogued as COSV55755334; called by muse, mutect2, varscan2
- GSPT1 | c.76G>A p.E26K (on ENST00000420576 / NM_001130007.2; = p.E164K on NM_002094.4) | Missense Mutation (SNP) | VAF 140/359 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.321); catalogued as rs912714309, COSV70452979; called by muse, mutect2, varscan2
- H2AC11 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); catalogued as COSV60362205, COSV60362617; called by muse, mutect2, varscan2
- H2BC13 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 88/256 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.246); catalogued as COSV100704343, COSV62440776; called by muse, mutect2, varscan2
- HADHB | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 147/371 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV58548158; called by muse, mutect2, varscan2
- HAUS5 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs986109845, COSV99178761; called by muse, mutect2
- HBS1L | c.756G>C p.E252D | Missense Mutation (SNP) | VAF 141/226 reads (62%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.524); catalogued as COSV63202605; called by muse, mutect2, varscan2
- HDLBP | c.3367G>A p.E1123K | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs768789088, COSV60499900; called by muse, mutect2, varscan2
- HDX | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 141/368 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs377491725, COSV52981803; called by muse, mutect2, varscan2
- HELZ2 | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV100915611; called by muse, mutect2
- HERC1 | c.6891G>C p.R2297S | Missense Mutation (SNP) | VAF 115/288 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV71249740; called by muse, mutect2, varscan2
- HHLA2 | c.214C>A p.H72N | Missense Mutation (SNP) | VAF 91/315 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV63319468; called by muse, mutect2, varscan2
- HIP1R | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 132/204 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as rs777793133, COSV53444058; called by muse, mutect2, varscan2
- HKDC1 | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 62/101 reads (61%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.455); catalogued as rs774217376, COSV63578890; called by muse, mutect2, varscan2
- HLA-F | c.1013G>A p.R338K | Missense Mutation (SNP) | VAF 115/195 reads (59%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.005); catalogued as COSV52576601, COSV99465561; called by muse, mutect2, varscan2
- HMCN1 | c.10609G>A p.E3537K | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54931908; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as COSV61255903; called by muse, mutect2, varscan2
- HPS3 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 151/525 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.853); catalogued as COSV56056930; called by muse, mutect2, varscan2
- HSP90AB1 | c.1604C>G p.S535* | Nonsense Mutation (SNP) | VAF 57/206 reads (28%) | catalogued as COSV62334578, COSV62335968; called by muse, mutect2, varscan2
- HSPBAP1 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 104/219 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60243483; called by muse, mutect2, varscan2
- HYDIN | c.9055G>C p.D3019H | Missense Mutation (SNP) | VAF 94/201 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59267176; called by muse, mutect2, varscan2
- ICE1 | c.2831C>T p.S944L | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs537336867, COSV56830628; called by muse, mutect2, varscan2
- ICE2 | c.277C>G p.P93A | Missense Mutation (SNP) | VAF 124/337 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55033541; called by muse, mutect2, varscan2
- IFT140 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as COSV68494574; called by muse, mutect2, varscan2
- IGSF1 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 24/311 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.081); catalogued as rs1215064968, COSV63836099; called by muse, mutect2
- IL13RA2 | c.29G>A p.C10Y | Missense Mutation (SNP) | VAF 75/252 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as COSV54567162; called by muse, mutect2, varscan2
- INCENP | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs1360515962, COSV53919924; called by muse, mutect2, varscan2
- IQGAP1 | c.3102C>G p.I1034M | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV51589936; called by muse, mutect2, varscan2
- IREB2 | c.2698G>A p.D900N | Missense Mutation (SNP) | VAF 113/330 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV51925949; called by muse, mutect2, varscan2
- IRF9 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.203); catalogued as COSV60703828; called by muse, mutect2, varscan2
- ITGA9 | c.2073G>C p.E691D | Missense Mutation (SNP) | VAF 120/221 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.147); catalogued as COSV53250482; called by muse, mutect2, varscan2
- ITIH2 | c.753C>G p.F251L | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV100623300; called by muse, mutect2
- JARID2 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV59196087; called by muse, mutect2, varscan2
- JPH4 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.162); catalogued as rs976189609, COSV58115042; called by muse, mutect2
- KAT5 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV57729664; called by muse, mutect2, varscan2
- KCNH2 | c.1074C>G p.I358M | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV51221787; called by muse, mutect2, varscan2
- KCNH5 | c.2188G>C p.E730Q | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.374); catalogued as COSV59773187; called by muse, mutect2, varscan2
- KCNJ2 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.518); catalogued as rs1378491441, COSV54663384; called by muse, mutect2, varscan2
- KCNQ3 | c.2287C>T p.Q763* | Nonsense Mutation (SNP) | VAF 28/47 reads (60%) | catalogued as COSV66479641; called by muse, mutect2, varscan2
- KCNQ5 | c.1386G>C p.Q462H | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as COSV59677759; called by muse, mutect2, varscan2
- KCTD1 | c.306C>G p.F102L | Missense Mutation (SNP) | VAF 99/271 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV58690129; called by muse, mutect2, varscan2
- KCTD20 | c.1067A>G p.E356G | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54804458; called by muse, mutect2, varscan2
- KIAA0100 | c.3038G>A p.R1013Q | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762692859, COSV66490901; called by muse, mutect2, varscan2
- KIAA1522 | c.2540C>T p.S847L (on ENST00000373480 / NM_001198972.2; = p.S906L on NM_020888.3) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs776125780, COSV53864939; called by muse, mutect2, varscan2
- KIF21B | c.2412G>C p.Q804H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59764209; called by muse, mutect2, varscan2
- KIF5A | c.1903C>T p.Q635* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV54058074; called by muse, mutect2, varscan2
- KIF7 | c.2874C>G p.S958R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.296); catalogued as rs759963623, COSV51545717; called by muse, mutect2, varscan2
- KL | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 78/189 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV66309755; called by muse, mutect2, varscan2
- KLF11 | c.771G>C p.Q257H | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV59941377; called by muse, mutect2, varscan2
- KNDC1 | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.099); catalogued as COSV58844357; called by muse, mutect2, varscan2
- KRT1 | c.650A>T p.Q217L | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52868723; called by muse, mutect2, varscan2
- L3MBTL3 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 96/136 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1463889794, COSV62388355; called by muse, mutect2, varscan2
- LAMA3 | c.4751G>A p.R1584Q | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as rs771786290, COSV52531433; called by muse, mutect2, varscan2
- LCT | c.1682C>G p.S561C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV51555890; called by muse, mutect2, varscan2
- LDLRAD4 | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); catalogued as rs753992992, COSV63341959; called by muse, mutect2, varscan2
- LEF1 | c.182C>G p.S61C | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54471970; called by muse, mutect2, varscan2
- LGR4 | c.2677G>C p.E893Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.068); catalogued as COSV58726900; called by muse, mutect2, varscan2
- LINGO4 | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 40/131 reads (31%) | catalogued as rs149393439; called by muse, mutect2, varscan2
- LPL | c.1003C>G p.Q335E | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.158); catalogued as COSV60932515; called by muse, mutect2, varscan2
- LRP2 | c.3166G>A p.D1056N | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55558862, COSV99787750; called by muse, mutect2, varscan2
- LRRC27 | c.250C>G p.Q84E | Missense Mutation (SNP) | VAF 136/264 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV59811233; called by muse, mutect2, varscan2
- LRRC46 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV51637080; called by muse, mutect2, varscan2
- LSG1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs200962492, COSV54568573, COSV54572161; called by muse, mutect2, varscan2
- LTN1 | c.2976G>C p.K992N | Missense Mutation (SNP) | VAF 149/378 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV63735002; called by muse, mutect2, varscan2
- LYRM2 | c.187-3C>G | Splice Region (SNP) | VAF 35/122 reads (29%) | catalogued as COSV60229030; called by muse, mutect2, varscan2
- MACF1 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 69/204 reads (34%) | catalogued as COSV58360780, COSV58396272; called by muse, mutect2, varscan2
- MAGEC3 | c.1159C>G p.L387V | Missense Mutation (SNP) | VAF 93/219 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.176); catalogued as COSV68924168; called by muse, mutect2, varscan2
- MAGED1 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.989); catalogued as COSV58514974, COSV58516485; called by muse, mutect2, varscan2
- MAGEE2 | c.1087T>C p.F363L | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV64898340; called by muse, mutect2, varscan2
- MAGI2 | c.3757G>C p.E1253Q | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV62648071, COSV62690145; called by muse, mutect2, varscan2
- MAGT1 | c.490G>A p.E164K (on ENST00000618282 / NM_001367916.1; = p.E196K on NM_032121.5) | Missense Mutation (SNP) | VAF 97/238 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63782814; called by muse, mutect2, varscan2
- MAP11 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.32); catalogued as rs758756246, COSV57587892; called by muse, mutect2, varscan2
- MAP4K1 | c.1633G>C p.V545L | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV67711197, COSV67712535; called by muse, varscan2
- MAP7D2 | c.1584G>C p.Q528H | Missense Mutation (SNP) | VAF 165/406 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV65526387; called by muse, mutect2, varscan2
- MAP7D3 | c.2309C>T p.S770L | Missense Mutation (SNP) | VAF 142/376 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as rs1278874420, COSV60172185; called by muse, mutect2, varscan2
- MAPKAPK2 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54318043; called by muse, mutect2, varscan2
- MARCHF11 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV60133457; called by muse, mutect2, varscan2
- MCF2 | c.2728G>C p.E910Q | Missense Mutation (SNP) | VAF 206/515 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV58492806; called by muse, mutect2, varscan2
- MCM6 | c.1218C>T p.L406= | Splice Region (SNP) | VAF 39/99 reads (39%) | catalogued as COSV51468721; called by muse, mutect2, varscan2
- MDGA1 | c.748C>G p.L250V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.063); catalogued as COSV51799676; called by muse, mutect2, varscan2
- MED12 | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100379663, COSV61352274; called by muse, mutect2, varscan2
- MED23 | c.797A>C p.Q266P | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100645049; called by muse, mutect2
- MET | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.517); catalogued as COSV59267180; called by muse, mutect2, varscan2
- METTL21C | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 39/304 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV57432706, COSV57432761; called by muse, mutect2, varscan2
- MFN2 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52425013; called by muse, mutect2, varscan2
- MIA2 | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 66/164 reads (40%) | catalogued as COSV54484151, COSV54485678; called by muse, mutect2, varscan2
- MICALL2 | c.1628C>T p.S543L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs143305148; called by muse, mutect2, varscan2
- MIDEAS | c.2860G>C p.E954Q | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV54094027, COSV54098025; called by muse, mutect2, varscan2
- MKRN3 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV58811711; called by muse, mutect2, varscan2
- MLH3 | c.3406G>T p.E1136* | Nonsense Mutation (SNP) | VAF 65/170 reads (38%) | catalogued as COSV53158002, COSV53158153; called by muse, mutect2, varscan2
- MMP2 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as COSV54604469; called by muse, mutect2, varscan2
- MON2 | c.1134G>A p.M378I | Missense Mutation (SNP) | VAF 191/708 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV54813286; called by muse, mutect2, varscan2
- MON2 | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 110/383 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as COSV54813307; called by muse, mutect2, varscan2
- MROH2B | c.4634G>C p.R1545T | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.109); catalogued as COSV68188353; called by muse, mutect2, varscan2
- MS4A2 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV54013582, COSV99627138; called by muse, mutect2, varscan2
- MSH6 | c.3083C>T p.S1028L | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs876660853, COSV52285711; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTX1 | c.994C>G p.Q332E | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.539); catalogued as COSV57426844; called by muse, mutect2, varscan2
- MUC16 | c.6233C>G p.S2078C | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.373); catalogued as COSV67442870, COSV67486793; called by muse, mutect2, varscan2
- MUC17 | c.6938C>G p.S2313C | Missense Mutation (SNP) | VAF 109/317 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV60300148; called by muse, mutect2, varscan2
- MUC17 | c.8492C>T p.S2831L | Missense Mutation (SNP) | VAF 113/286 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV100073597; called by muse, mutect2
- MYBPC1 | c.1337T>C p.L446P (on ENST00000550270 / NM_206820.2; = p.L471P on NM_002465.4) | Missense Mutation (SNP) | VAF 122/419 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as COSV62256722; called by muse, mutect2, varscan2
- MYH10 | c.1765G>C p.D589H | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV52608509; called by muse, mutect2, varscan2
- MYH13 | c.1667A>G p.D556G | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV99354202; called by muse, mutect2
- MYH8 | c.3355G>C p.E1119Q | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as COSV67970839; called by muse, mutect2, varscan2
- MYLK | c.3478G>A p.A1160T | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.609); catalogued as COSV60619422; called by muse, mutect2, varscan2
- MYO6 | c.3868C>G p.L1290V (on ENST00000369981; = p.L1280V on NM_004999.4) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as COSV64120088; called by muse, mutect2, varscan2
- MYT1L | c.3001G>A p.E1001K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV67701350; called by muse, mutect2, varscan2
- NCOA1 | c.2894G>A p.G965E | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.985); catalogued as rs754700681, COSV56051203; called by muse, mutect2, varscan2
- NCOA3 | c.1110G>C p.Q370H | Missense Mutation (SNP) | VAF 61/135 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.168); catalogued as COSV59072369; called by muse, mutect2, varscan2
- NEBL | c.2588C>G p.S863C | Missense Mutation (SNP) | VAF 180/306 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs150152361; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NECAP2 | c.420G>C p.Q140H | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV61434212; called by muse, mutect2, varscan2
- NEFM | c.2534G>A p.G845D | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.68); catalogued as rs188421098, COSV55334469; called by muse, mutect2, varscan2
- NEK10 | c.2775C>T p.F925= | Splice Region (SNP) | VAF 162/301 reads (54%) | catalogued as COSV55363662; called by muse, mutect2, varscan2
- NFS1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.003); catalogued as rs760067558, COSV60764648; called by muse, mutect2, varscan2
- NIBAN1 | c.805A>C p.K269Q | Missense Mutation (SNP) | VAF 77/339 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV62287176; called by muse, mutect2, varscan2
- NID2 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as COSV53493996, COSV53501423; called by muse, mutect2, varscan2
- NIPBL | c.2575G>C p.D859H | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.062); catalogued as COSV56962355; called by muse, mutect2, varscan2
- NLGN3 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100704838, COSV62442137; called by muse, mutect2, varscan2
- NLRP5 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as COSV66766849; called by muse, mutect2, varscan2
- NLRP7 | c.2018C>G p.S673* (on ENST00000340844 / NM_206828.3; = p.S645* on NM_139176.3) | Nonsense Mutation (SNP) | VAF 34/77 reads (44%) | catalogued as rs104895555, CM093048, COSV60178391; ClinVar: not provided; called by muse, mutect2, varscan2
- NOL4 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 115/302 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.37); catalogued as COSV52358575; called by muse, mutect2, varscan2
- NOP9 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV51867498; called by muse, mutect2, varscan2
- NPAS2 | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs564795063, COSV59561142; called by muse, mutect2, varscan2
- NPIPB15 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.225); catalogued as rs774890235, COSV70438285; called by muse, mutect2, varscan2
- NPPA | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); catalogued as rs1290847165, COSV56742557; called by muse, mutect2, varscan2
- NPSR1 | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV62206309; called by muse, mutect2, varscan2
- NR3C2 | c.1226C>G p.S409* | Nonsense Mutation (SNP) | VAF 48/127 reads (38%) | catalogued as COSV60998019; called by muse, mutect2, varscan2
- NRCAM | c.676C>G p.Q226E (on ENST00000379028 / NM_001371124.1; = p.Q220E on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/242 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV61046313; called by muse, mutect2, varscan2
- NRG1 | c.889C>T p.H297Y (on ENST00000405005 / NM_013964.5; = p.H302Y on NM_013956.5) | Missense Mutation (SNP) | VAF 139/232 reads (60%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV55172658; called by muse, mutect2, varscan2
- NSD1 | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.082); catalogued as rs1208967470, COSV61777862; called by muse, mutect2, varscan2
- NSUN3 | c.764G>T p.R255L | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV58937382, COSV58938351; called by muse, mutect2, varscan2
- NTRK1 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.317); catalogued as rs752584213, COSV62324140, COSV62327964; called by muse, mutect2, varscan2
- NUMB | c.1942G>C p.E648Q (on ENST00000355058; = p.E637Q on NM_003744.5) | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53722242; called by muse, mutect2, varscan2
- NUP133 | c.3274C>G p.P1092A | Missense Mutation (SNP) | VAF 143/595 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54574520, COSV99772730; called by muse, mutect2, varscan2
- NUSAP1 | c.783G>C p.Q261H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV52972812; called by muse, mutect2, varscan2
- NXN | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 122/317 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV61099611; called by muse, mutect2, varscan2
- NYX | c.1017C>G p.C339W | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV61180768, COSV61181517; called by muse, mutect2, varscan2
- OBI1 | c.1508C>G p.S503* | Nonsense Mutation (SNP) | VAF 53/155 reads (34%) | catalogued as rs1381270023, COSV56146894; called by muse, mutect2, varscan2
- OBSCN | c.18203G>A p.G6068D | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767750514, COSV52815513; called by muse, mutect2, varscan2
- OR10A3 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 66/127 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs754413151, COSV62459165, COSV62460613; called by muse, mutect2, varscan2
- OR10G9 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66686681; called by muse, mutect2, varscan2
- OR11H1 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs1198642223, COSV53272475; called by mutect2, varscan2
- OR2L8 | c.785G>A p.R262K | Missense Mutation (SNP) | VAF 111/489 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0.014); catalogued as COSV61727974; called by muse, varscan2
- OR2T1 | c.188G>T p.S63I | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100822318, COSV100822376; called by muse, mutect2
- OR4D6 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV55660749; called by muse, mutect2, varscan2
- OR52L1 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 102/244 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as rs769447054, COSV59987698; called by muse, mutect2, varscan2
- OR52M1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV64172583; called by muse, mutect2, varscan2
- OR5B21 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV64482195, COSV64482372; called by muse, mutect2, varscan2
- OR5H14 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 247/854 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101454202; called by muse, mutect2
- OR6S1 | c.433C>A p.R145S | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as COSV57838714, COSV57839034; called by muse, mutect2, varscan2
- PCDH9 | c.3166C>A p.P1056T (on ENST00000377865 / NM_203487.3; = p.P1022T on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.395); catalogued as COSV60581569; called by muse, mutect2, varscan2
- PCDHB12 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.127); catalogued as COSV53394407, COSV53400059; called by muse, mutect2, varscan2
- PCNX2 | c.4399G>A p.E1467K | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs756649176, COSV50855378, COSV50859476; called by muse, mutect2, varscan2
- PDS5B | c.4319G>A p.R1440Q | Missense Mutation (SNP) | VAF 114/287 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.947); catalogued as COSV59726821; called by muse, mutect2, varscan2
- PEAK1 | c.2842G>C p.E948Q | Missense Mutation (SNP) | VAF 108/280 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs755359510, COSV56941653; called by muse, mutect2, varscan2
- PEF1 | c.561G>C p.K187N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV101035899, COSV65484200; called by muse, mutect2, varscan2
- PEG3 | c.3579G>A p.M1193I | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV55644167, COSV99688353; called by muse, mutect2, varscan2
- PEX5 | c.430T>A p.F144I | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV99870983; called by muse, mutect2
- PGM3 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 181/307 reads (59%) | SIFT tolerated (0.85); PolyPhen benign (0.068); catalogued as COSV52285599; called by muse, mutect2, varscan2
- PHACTR2 | c.1627G>C p.E543Q | Missense Mutation (SNP) | VAF 64/321 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV59857690; called by muse, mutect2, varscan2
- PHB2 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54643605, COSV99781311; called by muse, mutect2, varscan2
- PHF6 | c.5C>G p.S2* | Nonsense Mutation (SNP) | VAF 62/146 reads (42%) | catalogued as COSV59703744; called by muse, mutect2, varscan2
- PHIP | c.3289G>C p.D1097H | Missense Mutation (SNP) | VAF 87/288 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51508788; called by muse, mutect2, varscan2
- PHKA1 | c.3298-1G>A p.X1100_splice | Splice Site (SNP) | VAF 55/120 reads (46%) | catalogued as COSV59810074; called by muse, mutect2, varscan2
- PHTF1 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as COSV63368677; called by muse, mutect2, varscan2
- PIK3CB | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 164/593 reads (28%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.523); catalogued as rs1217537873, COSV56683158; called by muse, mutect2, varscan2
- PIK3CG | c.3052C>G p.L1018V | Missense Mutation (SNP) | VAF 93/209 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV63248005, COSV63252235; called by muse, mutect2, varscan2
- PIK3R1 | c.1721G>C p.R574T (on ENST00000521381 / NM_181523.3; = p.R304T on NM_181504.4) | Missense Mutation (SNP) | VAF 157/437 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV57125227, COSV57128628, COSV99144283; called by muse, mutect2, varscan2
- PKHD1 | c.5033C>G p.S1678* | Nonsense Mutation (SNP) | VAF 64/92 reads (70%) | catalogued as COSV61890735; called by muse, mutect2, varscan2
- PLCD4 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 137/313 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.195); catalogued as COSV68843254; called by muse, mutect2, varscan2
- PLCG1 | c.3033C>G p.I1011M | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54822705; called by muse, mutect2, varscan2
- PLEKHG4B | c.791G>A p.R264K (on ENST00000283426; = p.R620K on NM_052909.5) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV52053418; called by muse, mutect2, varscan2
- PNISR | c.2123A>G p.D708G | Missense Mutation (SNP) | VAF 21/865 reads (2%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); catalogued as rs1313507099, COSV100984375; called by muse, mutect2
- PNN | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 195/525 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV53768009; called by muse, mutect2, varscan2
- PNN | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 132/326 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); catalogued as COSV53768020; called by muse, varscan2
- PNN | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV53768030, COSV99397297; called by muse, varscan2
- POLDIP2 | c.1033G>C p.D345H | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV50228824; called by muse, mutect2, varscan2
- POLQ | c.4786C>G p.P1596A | Missense Mutation (SNP) | VAF 134/474 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV51759360; called by muse, mutect2, varscan2
- POLQ | c.4435C>G p.P1479A | Missense Mutation (SNP) | VAF 99/341 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV51759374; called by muse, mutect2, varscan2
- POLR1D | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 114/309 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV68799526, COSV68799985; called by muse, mutect2, varscan2
- POLR1E | c.835G>A p.E279K (on ENST00000377792 / NM_001282766.1; = p.E217K on NM_022490.4) | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.398); catalogued as COSV66772910; called by muse, mutect2, varscan2
- POLR2B | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 86/221 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58902272; called by muse, mutect2, varscan2
- POM121 | c.3212C>G p.S1071C (on ENST00000434423; = p.S806C on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57522588; called by muse, mutect2, varscan2
- PPFIA3 | c.2289C>G p.I763M | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV61954099; called by muse, varscan2
- PPFIA4 | c.1597C>T p.R533C (on ENST00000447715; = p.R508C on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1387806788; called by muse, mutect2
- PPIP5K2 | c.2435C>T p.S812F | Missense Mutation (SNP) | VAF 189/473 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58608798; called by muse, mutect2, varscan2
- PPP1R21 | c.244C>G p.L82V | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.998); catalogued as COSV54287864, COSV99682122; called by muse, mutect2, varscan2
- PREX1 | c.4441C>T p.P1481S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs778413291, COSV64255711; called by muse, mutect2, varscan2
- PRICKLE3 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs924173387, COSV66234551; called by muse, mutect2, varscan2
- PRKDC | c.8546C>T p.S2849F | Missense Mutation (SNP) | VAF 168/597 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV58060892; called by muse, mutect2, varscan2
- PRKDC | c.841C>G p.Q281E | Missense Mutation (SNP) | VAF 160/278 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV58060902; called by muse, mutect2, varscan2
- PRKN | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769230602, COSV58202909, COSV58220892, COSV58225018; called by muse, mutect2
- PROM1 | c.56C>G p.S19* | Nonsense Mutation (SNP) | VAF 54/125 reads (43%) | catalogued as COSV71699901; called by muse, mutect2, varscan2
- PSAPL1 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.635); catalogued as COSV59844189; called by muse, mutect2, varscan2
- PSEN2 | c.413C>G p.S138C | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60914867, COSV60917821; called by muse, mutect2, varscan2
- PSG3 | c.711G>A p.P237= | Splice Region (SNP) | VAF 212/492 reads (43%) | catalogued as rs2353157, COSV59505528; called by muse, mutect2, varscan2
- PTDSS1 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 20/450 reads (4%) | catalogued as COSV100428692; called by muse, mutect2
- PTGDR | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 88/262 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV60093363; called by muse, mutect2, varscan2
- PTPN9 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs541229442, COSV60725502; called by muse, mutect2, varscan2
- PTPRE | c.512-1G>C p.X171_splice | Splice Site (SNP) | VAF 168/626 reads (27%) | catalogued as COSV54557292; called by muse, varscan2
- PTPRR | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 346/595 reads (58%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as COSV51744378; called by muse, mutect2, varscan2
- PZP | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.1); catalogued as COSV54368312; called by muse, mutect2, varscan2
- QSER1 | c.3961G>C p.D1321H (on ENST00000399302; = p.D1450H on NM_001076786.3) | Missense Mutation (SNP) | VAF 142/340 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs563561881, COSV67900139; called by muse, mutect2, varscan2
- RARS2 | c.1540C>G p.Q514E | Missense Mutation (SNP) | VAF 119/411 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV65762305; called by muse, mutect2, varscan2
- RBM27 | c.590-1G>A p.X197_splice | Splice Site (SNP) | VAF 54/127 reads (43%) | catalogued as COSV54593257; called by muse, varscan2
- RBMS2 | c.1062G>A p.T354= | Splice Region (SNP) | VAF 61/201 reads (30%) | catalogued as rs374841391; called by muse, mutect2, varscan2
- RBSN | c.1453C>G p.L485V | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53791331, COSV53795108; called by muse, mutect2, varscan2
- RELN | c.7447G>C p.D2483H | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV59028281; called by muse, mutect2, varscan2
- RESF1 | c.3286G>A p.D1096N | Missense Mutation (SNP) | VAF 87/262 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.234); catalogued as COSV57021352; called by muse, mutect2, varscan2
- RFC4 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 219/383 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.368); catalogued as COSV56218290; called by muse, mutect2, varscan2
- RGS4 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 87/461 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV63358010; called by muse, mutect2, varscan2
- RGS4 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 216/503 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as rs756789482, COSV63358018; called by muse, mutect2, varscan2
- RIMBP2 | c.2619G>C p.E873D | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV55481589, COSV99898277; called by muse, mutect2, varscan2
- RNF139 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 158/305 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52681573; called by muse, mutect2, varscan2
- RNF14 | c.109A>G p.R37G | Missense Mutation (SNP) | VAF 109/269 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.268); catalogued as COSV61662800; called by muse, mutect2, varscan2
- RNF217 | c.973G>C p.E325Q (on ENST00000521654 / NM_001286398.2; = p.E33Q on NM_152553.5) | Missense Mutation (SNP) | VAF 149/239 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV51577213, COSV51577901; called by muse, mutect2, varscan2
- RNPEP | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 77/402 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV55240605, COSV55243577; called by muse, mutect2, varscan2
- RORC | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 102/226 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV59094950, COSV59095086; called by muse, mutect2, varscan2
- RP1 | c.2303C>G p.S768C | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.408); catalogued as rs1162608680, COSV55110595, COSV55111673; called by muse, mutect2, varscan2
- RPGRIP1L | c.3181G>A p.E1061K | Missense Mutation (SNP) | VAF 157/379 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.298); catalogued as COSV50914213; called by muse, mutect2, varscan2
- RPS6 | c.647G>A p.R216K | Missense Mutation (SNP) | VAF 96/220 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.421); catalogued as COSV100194386, COSV59548683; called by muse, mutect2, varscan2
- RPS6KA2 | c.1978C>T p.R660C | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1477628615, COSV99691137; called by muse, mutect2, varscan2
- RTN1 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1316938867, COSV50718696, COSV50732818; called by muse, mutect2, varscan2
- RYR2 | c.2723G>C p.R908T | Missense Mutation (SNP) | VAF 82/201 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV63707250; called by muse, mutect2, varscan2
- SALL2 | c.726C>G p.F242L | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); catalogued as COSV58105325; called by muse, mutect2, varscan2
- SAMD15 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1047273724, COSV53627687; called by muse, varscan2
- SAMD15 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV53627691; called by muse, varscan2
- SAV1 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as rs1393932581, COSV61205560; called by muse, mutect2, varscan2
- SCAF4 | c.2378G>C p.R793T | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV54591264; called by muse, mutect2, varscan2
- SCAP | c.2045C>T p.P682L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs770058714; called by muse, varscan2
- SCN7A | c.2498C>G p.S833* | Nonsense Mutation (SNP) | VAF 164/417 reads (39%) | catalogued as COSV69274070; called by muse, mutect2, varscan2
- SCN9A | c.5350G>A p.E1784K (on ENST00000303354; = p.E1773K on NM_002977.3) | Missense Mutation (SNP) | VAF 173/431 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV57620961; called by muse, mutect2, varscan2
- SCYL2 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 143/255 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV62570372; called by muse, mutect2, varscan2
- SEC24D | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 61/163 reads (37%) | catalogued as COSV54883763; called by muse, mutect2, varscan2
- SEMA4C | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs764755720, COSV100560716, COSV59691828; called by muse, mutect2, varscan2
- SERPINB4 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 181/453 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.963); catalogued as COSV61985964; called by muse, mutect2, varscan2
- SHKBP1 | c.1272G>C p.Q424H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52542651; called by muse, mutect2, varscan2
- SIGLEC10 | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs376850541; called by muse, mutect2, varscan2
- SIN3A | c.2658C>G p.F886L | Missense Mutation (SNP) | VAF 118/333 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as rs1369700335, COSV64582901, COSV64584497; called by muse, mutect2, varscan2
- SLC10A6 | c.830C>G p.S277C | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56722137, COSV56723163, COSV99907091; called by muse, mutect2, varscan2
- SLC1A3 | c.803G>A p.R268K | Missense Mutation (SNP) | VAF 124/295 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1371499415, COSV54319386; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC1A4 | c.1420C>G p.L474V | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.759); catalogued as COSV52235697; called by muse, mutect2, varscan2
- SLC25A20 | c.291G>C p.K97N | Missense Mutation (SNP) | VAF 96/168 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59804496, COSV59804591; called by muse, mutect2, varscan2
- SLC26A5 | c.2098G>C p.E700Q | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV100099432; called by muse, mutect2
- SLC2A1 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV65288193; called by muse, mutect2, varscan2
- SLC35G6 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV59495182; called by muse, mutect2, varscan2
- SLC38A4 | c.1175-1G>T p.X392_splice | Splice Site (SNP) | VAF 64/211 reads (30%) | catalogued as COSV56970523; called by muse, mutect2, varscan2
- SLC4A4 | c.562G>A p.D188N (on ENST00000264485 / NM_001098484.3; = p.D144N on NM_003759.4) | Missense Mutation (SNP) | VAF 83/188 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV52634916; called by muse, mutect2, varscan2
- SLC9A7 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as rs1231947331, COSV60379704; called by muse, mutect2, varscan2
- SLIT2 | c.2524G>C p.E842Q | Missense Mutation (SNP) | VAF 260/682 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV56561268, COSV99884293; called by muse, mutect2
- SMARCE1 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV52861673; called by muse, mutect2, varscan2
- SMC4 | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 62/233 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV61004925, COSV61007316; called by muse, mutect2, varscan2
- SMC6 | c.2943C>A p.F981L | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV61177624; called by muse, mutect2, varscan2
- SMPDL3A | c.585G>C p.Q195H | Missense Mutation (SNP) | VAF 349/516 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63755769; called by muse, mutect2, varscan2
- SMTN | c.2745G>C p.K915N | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as COSV60781685; called by muse, mutect2, varscan2
- SORL1 | c.6640G>A p.A2214T | Missense Mutation (SNP) | VAF 126/309 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52760891; called by muse, mutect2, varscan2
- SOS2 | c.2428G>C p.E810Q | Missense Mutation (SNP) | VAF 168/487 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV53572830; called by muse, mutect2, varscan2
- SPATA16 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 168/573 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.909); catalogued as COSV63532318; called by muse, mutect2, varscan2
- SPATA31E1 | c.1522C>A p.P508T | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV57794417; called by muse, mutect2, varscan2
- SPEG | c.6607C>T p.P2203S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV56677708; called by muse, mutect2, varscan2
- SPRY3 | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV57144063; called by muse, mutect2, varscan2
- SPTA1 | c.5193G>C p.E1731D | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as COSV63757901; called by muse, mutect2, varscan2
- SPTA1 | c.4060G>A p.E1354K | Missense Mutation (SNP) | VAF 56/274 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.201); catalogued as COSV63757903; called by muse, mutect2, varscan2
- SPX | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); catalogued as rs747839085, COSV57021604; called by muse, mutect2, varscan2
- SRCAP | c.8197C>T p.Q2733* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV52679144; called by muse, mutect2, varscan2
- SSRP1 | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 122/295 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as COSV53481062; called by muse, mutect2, varscan2
- ST18 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 254/442 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV52505875; called by mutect2, varscan2
- STK3 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 69/287 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV69226279; called by muse, mutect2, varscan2
- STK33 | c.239C>G p.S80* | Nonsense Mutation (SNP) | VAF 105/254 reads (41%) | catalogued as COSV59396141; called by muse, mutect2, varscan2
- STMN4 | c.331G>A p.E111K (on ENST00000265770 / NM_001283054.2; = p.E138K on NM_030795.4) | Missense Mutation (SNP) | VAF 150/499 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV56110037; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 89/183 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs763073965, COSV59125932; called by muse, mutect2, varscan2
- SUPT16H | c.2227G>C p.E743Q | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV104369733, COSV53527152; called by muse, mutect2, varscan2
- SUPT6H | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV58929900; called by muse, mutect2, varscan2
- SYNE2 | c.4336G>A p.V1446M | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); catalogued as rs757289089, COSV59965487; called by muse, mutect2, varscan2
- SYT10 | c.1248G>C p.K416N | Missense Mutation (SNP) | VAF 410/724 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57342354, COSV57344364; called by muse, varscan2
- TASOR | c.2221C>G p.P741A (on ENST00000355628 / NM_001365636.2; = p.P345A on NM_015224.3) | Missense Mutation (SNP) | VAF 82/156 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV62929329; called by muse, mutect2
- TBC1D15 | c.1954C>G p.P652A | Missense Mutation (SNP) | VAF 101/372 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV59849393, COSV59852233; called by muse, mutect2, varscan2
- TBL1X | c.1606-1G>A p.X536_splice | Splice Site (SNP) | VAF 21/69 reads (30%) | catalogued as COSV54286882; called by muse, mutect2, varscan2
- TBL1XR1 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 347/608 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV70503088; called by muse, mutect2, varscan2
- TCF20 | c.2612C>G p.S871C | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV59495104; called by muse, mutect2, varscan2
- TEAD3 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV58818198; called by muse, mutect2, varscan2
- TEK | c.1702C>G p.P568A | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV66232306; called by muse, mutect2, varscan2
- TESPA1 | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57260792; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV51515231; called by muse, mutect2, varscan2
- THNSL2 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV59084375; called by muse, mutect2, varscan2
- TIMMDC1 | c.295C>G p.H99D | Missense Mutation (SNP) | VAF 97/361 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV51787783; called by muse, mutect2, varscan2
- TNFRSF17 | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV50001749; called by muse, mutect2, varscan2
- TNFSF13 | c.551G>C p.R184P | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53433750; called by muse, mutect2, varscan2
- TNS3 | c.1876C>G p.Q626E | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV60797027; called by muse, mutect2, varscan2
- TOGARAM1 | c.4391C>G p.S1464* | Nonsense Mutation (SNP) | VAF 62/150 reads (41%) | catalogued as COSV63894373; called by muse, mutect2, varscan2
- TP53BP1 | c.1663C>G p.L555V | Missense Mutation (SNP) | VAF 127/311 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV55507136; called by muse, mutect2, varscan2
- TPH1 | c.362G>C p.R121T | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.851); catalogued as COSV51459851; called by muse, mutect2, varscan2
- TPP1 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); catalogued as COSV54995046; called by muse, mutect2, varscan2
- TPTE2 | c.617C>T p.S206L (on ENST00000400230 / NM_199254.2; = p.S129L on NM_130785.3) | Missense Mutation (SNP) | VAF 137/424 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55026578; called by muse, mutect2, varscan2
- TRA2B | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV99373271; called by muse, mutect2
- TRAPPC9 | c.2298C>G p.F766L | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.356); catalogued as COSV101227167, COSV66907982; called by muse, mutect2, varscan2
- TRIM13 | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV100078627, COSV53951265; called by muse, mutect2, varscan2
- TRIM13 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 105/302 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV53948571, COSV53951282; called by muse, varscan2
- TRPC6 | c.1647G>A p.W549* | Nonsense Mutation (SNP) | VAF 85/207 reads (41%) | catalogued as COSV60259411; called by muse, mutect2, varscan2
- TRRAP | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV62852272; called by muse, mutect2, varscan2
- TTC26 | c.78G>C p.K26N | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV58273878; called by muse, mutect2, varscan2
- TTC27 | c.1833-1G>C p.X611_splice | Splice Site (SNP) | VAF 72/191 reads (38%) | catalogued as COSV58655815; called by muse, varscan2
- TTC29 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.282); catalogued as rs760572838, COSV57273510; called by muse, mutect2, varscan2
- TTC37 | c.4688C>G p.S1563* | Nonsense Mutation (SNP) | VAF 121/366 reads (33%) | catalogued as COSV62456423; called by muse, mutect2, varscan2
- TTC8 | c.979G>A p.A327T (on ENST00000338104 / NM_001288781.1; = p.A311T on NM_144596.4) | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV57629947; called by muse, mutect2, varscan2
- TTN | c.101087C>G p.S33696* (on ENST00000591111; = p.S26272* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 163/407 reads (40%) | catalogued as COSV60278898; called by muse, mutect2, varscan2
- TTN | c.24698G>T p.R8233M (on ENST00000591111; = p.R7306M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/122 reads (6%) | PolyPhen possibly damaging (0.732); catalogued as COSV100615847, COSV100627061; called by muse, mutect2
- UBA6 | c.842C>A p.P281Q | Missense Mutation (SNP) | VAF 86/198 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV59180451; called by muse, mutect2, varscan2
- UBE3D | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 279/472 reads (59%) | catalogued as COSV52755109, COSV52756544; called by muse, mutect2, varscan2
- UGGT2 | c.3181G>A p.E1061K | Missense Mutation (SNP) | VAF 91/226 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV65078317; called by muse, mutect2, varscan2
- UGT3A2 | c.744C>A p.F248L | Missense Mutation (SNP) | VAF 101/305 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.046); catalogued as COSV56932803; called by muse, mutect2, varscan2
- USE1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1287593162, COSV55728666; called by muse, mutect2, varscan2
- USH2A | c.14650G>A p.E4884K | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV56343179; called by muse, mutect2, varscan2
- USP39 | c.1323C>G p.F441L | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV60383096; called by muse, mutect2, varscan2
- USP44 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 88/178 reads (49%) | catalogued as COSV51566324; called by muse, mutect2, varscan2
- USP6NL | c.1987C>G p.Q663E | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.026); catalogued as COSV53214638; called by muse, mutect2, varscan2
- UTP20 | c.2501G>C p.R834T | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.835); catalogued as COSV55383752; called by muse, mutect2, varscan2
- VPS13A | c.4788G>C p.M1596I | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV62433136, COSV62436921; called by muse, mutect2, varscan2
- VPS13B | c.6207G>C p.K2069N | Missense Mutation (SNP) | VAF 80/276 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV62153789; called by muse, mutect2, varscan2
- VPS13D | c.8327C>G p.S2776C | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV50669566, COSV99169226; called by muse, mutect2, varscan2
- VPS36 | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 92/231 reads (40%) | catalogued as COSV65199865; called by muse, mutect2, varscan2
- VWA8 | c.2621G>A p.G874E | Missense Mutation (SNP) | VAF 170/409 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55703258; called by muse, mutect2, varscan2
- ZC3H12C | c.937G>C p.E313Q | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53708436; called by muse, varscan2
- ZC3H12C | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53711925; called by muse, varscan2
- ZC3H6 | c.3026C>G p.S1009* | Nonsense Mutation (SNP) | VAF 51/141 reads (36%) | catalogued as COSV59670043; called by muse, mutect2, varscan2
- ZEB2 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 166/425 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV57964454; called by muse, mutect2, varscan2
- ZFHX4 | c.6178C>T p.P2060S | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); catalogued as COSV51489146; called by muse, mutect2, varscan2
- ZFP2 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV63726763; called by muse, mutect2, varscan2
- ZFP42 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV58818297; called by muse, mutect2, varscan2
- ZFP90 | c.1471C>G p.H491D | Missense Mutation (SNP) | VAF 84/197 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV68051271; called by muse, mutect2, varscan2
- ZHX2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV58716212; called by muse, mutect2, varscan2
- ZNF146 | c.751C>G p.Q251E | Missense Mutation (SNP) | VAF 81/194 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.875); catalogued as COSV61932497; called by muse, mutect2, varscan2
- ZNF296 | c.471G>C p.L157F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.092); catalogued as COSV99673863; called by muse, mutect2
- ZNF320 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 136/346 reads (39%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV67088780; called by muse, mutect2, varscan2
- ZNF322 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 329/793 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs1554148018, COSV70652219; called by muse, mutect2, varscan2
- ZNF341 | c.342C>G p.I114M | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV61010653; called by muse, mutect2, varscan2
- ZNF341 | c.1549G>A p.D517N (on ENST00000375200 / NM_001282935.1; = p.D510N on NM_032819.4) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs147280029; called by muse, mutect2, varscan2
- ZNF35 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56077287; called by muse, mutect2, varscan2
- ZNF408 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV61239061; called by muse, mutect2, varscan2
- ZNF483 | c.1691C>T p.S564L | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV58516965; called by muse, mutect2, varscan2
- ZNF513 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.4); PolyPhen benign (0.056); catalogued as rs781421899, COSV52009827; called by muse, mutect2, varscan2
- ZNF518A | c.3928G>C p.E1310Q | Missense Mutation (SNP) | VAF 61/240 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100283516, COSV60152981; called by muse, mutect2, varscan2
- ZNF518A | c.4367G>C p.R1456T | Missense Mutation (SNP) | VAF 103/334 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100283548; called by muse, mutect2, varscan2
- ZNF526 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.137); catalogued as COSV56631235; called by muse, mutect2, varscan2
- ZNF526 | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV56629798, COSV56631245; called by muse, mutect2, varscan2
- ZNF549 | c.1300G>A p.E434K (on ENST00000376233 / NM_001199295.2; = p.E421K on NM_153263.2) | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as rs1450788673, COSV53727371; called by muse, mutect2, varscan2
- ZNF557 | c.238G>A p.D80N (on ENST00000414706 / NM_001044388.2; = p.D87N on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.811); catalogued as COSV53275057; called by muse, mutect2, varscan2
- ZNF570 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.104); catalogued as COSV57578787; called by muse, mutect2, varscan2
- ZNF599 | c.738G>A p.M246I | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs370191399; called by muse, mutect2, varscan2
- ZNF600 | c.1882C>T p.H628Y | Missense Mutation (SNP) | VAF 128/332 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV57744692; called by muse, mutect2, varscan2
- ZNF630 | c.1009C>T p.H337Y | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52097897; called by muse, mutect2, varscan2
- ZNF75A | c.742C>T p.H248Y | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs1032363826, COSV73039558; called by muse, mutect2, varscan2
- ZNF770 | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs567596465, COSV62544844; called by muse, mutect2, varscan2
- ZRANB2 | c.39G>A p.W13* | Nonsense Mutation (SNP) | VAF 41/121 reads (34%) | catalogued as COSV54673936; called by muse, mutect2, varscan2
- ZZEF1 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 89/240 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.338); catalogued as rs938426225, COSV67559720; called by muse, mutect2, varscan2
- DDX3X | c.1806_1816del p.Q603Cfs*23 (on ENST00000399959; = p.Q604Cfs*23 on NM_001356.5) | Frame Shift Del (DEL) | VAF 26/104 reads (25%) | called by pindel, varscan2
- GPR179 | c.6424G>C p.E2142Q (on ENST00000621958; = p.E2141Q on NM_001004334.4) | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- IGLV2-23 | c.272C>A p.T91K | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); called by muse, mutect2
- KDM3B | c.494del p.N165Tfs*10 | Frame Shift Del (DEL) | VAF 36/348 reads (10%) | called by mutect2, pindel, varscan2
- KDM5C | c.3869_3874del p.G1290_R1291del | In Frame Del (DEL) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- MORC4 | c.642dup p.G215Rfs*13 | Frame Shift Ins (INS) | VAF 76/220 reads (35%) | called by mutect2, pindel, varscan2
- NBPF11 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 200/1124 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.849); called by muse, varscan2
- PNN | c.658_661delinsAAA p.E220Kfs*10 | Frame Shift Del (DEL) | VAF 67/290 reads (23%) | called by pindel, varscan2*
- POLR2A | c.3454G>A p.E1152K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); called by muse, mutect2
- SLC18A1 | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.235); called by muse, mutect2
- TADA2A | c.1076G>A p.R359K | Missense Mutation (SNP) | VAF 87/223 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- A2ML1 | c.1605G>A p.V535= | Silent (SNP) | VAF 245/430 reads (57%) | catalogued as rs1475563982, COSV55296926; called by muse, mutect2, varscan2
- AACS | c.1995C>T p.D665= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV55539724; called by muse, mutect2, varscan2
- ABCA12 | c.1338C>T p.F446= (on ENST00000272895 / NM_173076.3; = p.F128= on NM_015657.3) | Silent (SNP) | VAF 55/138 reads (40%) | catalogued as COSV55972197; called by muse, mutect2, varscan2
- ABCC4 | c.24G>C p.V8= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV100972540; called by muse, mutect2
- ACLY | c.541C>T p.L181= | Silent (SNP) | VAF 51/120 reads (43%) | catalogued as COSV61252507; called by muse, mutect2, varscan2
- ADAMTS19 | c.3543G>C p.V1181= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV50785677; called by muse, mutect2, varscan2
- ADAMTSL3 | c.165C>T p.F55= | Silent (SNP) | VAF 132/277 reads (48%) | catalogued as COSV54437415; called by muse, mutect2, varscan2
- ADCY7 | c.2001G>A p.L667= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV54269996; called by muse, mutect2, varscan2
- ADRB2 | c.1113G>A p.E371= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as rs377758965; called by muse, mutect2, varscan2
- AFDN | c.1551G>C p.L517= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as COSV60053597; called by muse, mutect2, varscan2
- AFF4 | c.2115C>G p.L705= | Silent (SNP) | VAF 156/388 reads (40%) | catalogued as COSV54798392; called by muse, mutect2, varscan2
- AHRR | c.816C>T p.P272= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs761611426, COSV57092023; called by muse, mutect2, varscan2
- AIM2 | c.477G>A p.L159= | Silent (SNP) | VAF 58/256 reads (23%) | catalogued as COSV63698426; called by muse, mutect2, varscan2
- ALOX5 | c.1965G>A p.K655= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV65553954; called by muse, mutect2, varscan2
- AMY2A | c.603C>G p.L201= | Silent (SNP) | VAF 177/798 reads (22%) | catalogued as COSV70214860; called by muse, mutect2, varscan2
- ANK1 | c.4530G>A p.Q1510= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV55892427, COSV99226756; called by muse, mutect2, varscan2
- ANXA6 | c.675G>A p.P225= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as rs373984263; called by muse, mutect2, varscan2
- APCDD1 | c.291C>T p.F97= | Silent (SNP) | VAF 46/110 reads (42%) | catalogued as COSV62373170; called by muse, mutect2, varscan2
- ASB12 | c.63C>A p.L21= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV62857589; called by muse, mutect2, varscan2
- ASXL1 | c.804C>T p.I268= | Silent (SNP) | VAF 94/234 reads (40%) | catalogued as COSV60118449; called by muse, mutect2, varscan2
- ATG7 | c.30C>G p.L10= | Silent (SNP) | VAF 90/325 reads (28%) | catalogued as rs1358490789, COSV61615101; called by muse, mutect2, varscan2
- ATG9B | c.1764C>G p.L588= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs1323857956, COSV99872186; called by muse, mutect2
- ATP5MC2 | c.324G>A p.L108= | Silent (SNP) | VAF 70/230 reads (30%) | catalogued as COSV58602069; called by muse, mutect2, varscan2
- AURKB | c.972C>T p.H324= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs762312141, COSV60245667; called by muse, mutect2, varscan2
- CERT1 | c.1332G>C p.L444= (on ENST00000405807 / NM_001130105.1; = p.L316= on NM_005713.3) | Silent (SNP) | VAF 143/369 reads (39%) | catalogued as COSV54663394; called by muse, mutect2, varscan2
- CFAP20DC | c.1218G>A p.L406= (on ENST00000482387 / NM_001351530.2; = p.L281= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 271/482 reads (56%) | catalogued as COSV55925962; called by muse, mutect2, varscan2
- CFAP54 | c.5670C>T p.I1890= | Silent (SNP) | VAF 53/184 reads (29%) | catalogued as rs150430019, COSV61574598; called by muse, mutect2, varscan2
- CLSTN1 | c.162C>T p.L54= | Silent (SNP) | VAF 78/178 reads (44%) | catalogued as COSV63650415; called by muse, mutect2, varscan2
- CNGA4 | c.1050G>A p.Q350= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV66006834; called by muse, mutect2, varscan2
- CNGB3 | c.2352C>G p.L784= | Silent (SNP) | VAF 316/598 reads (53%) | catalogued as COSV60696374; called by muse, mutect2, varscan2
- COL9A2 | c.888G>A p.P296= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs376866320; ClinVar: likely benign; called by muse, mutect2, varscan2
- CPA5 | c.366G>A p.A122= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs781792007, COSV62569153; called by muse, mutect2, varscan2
- CRTAC1 | c.1188C>T p.D396= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs765528825, COSV54008046; called by muse, mutect2, varscan2
- CSMD1 | c.1326C>T p.I442= (on ENST00000520002; = p.I441= on NM_033225.6) | Silent (SNP) | VAF 67/125 reads (54%) | catalogued as rs766723328, COSV68247214; called by muse, mutect2, varscan2
- CTBP2 | c.429C>T p.L143= | Silent (SNP) | VAF 21/31 reads (68%) | catalogued as rs745919237, COSV58337307; called by muse, mutect2, varscan2
- CYP4F12 | c.459C>T p.P153= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as rs199991130, COSV100215575; called by muse, mutect2, varscan2
- CYP4F3 | c.1467C>T p.F489= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs1469522445, COSV55407366, COSV55412951; called by muse, mutect2, varscan2
- DDC | c.87C>G p.V29= | Silent (SNP) | VAF 53/115 reads (46%) | catalogued as rs766496759, COSV63567214; called by muse, mutect2, varscan2
- DNAH2 | c.7023C>T p.L2341= | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as COSV66724914; called by muse, mutect2, varscan2
- DNAH3 | c.6627C>T p.I2209= | Silent (SNP) | VAF 90/246 reads (37%) | catalogued as COSV54544678; called by muse, mutect2, varscan2
- DOCK1 | c.3123G>A p.E1041= | Silent (SNP) | VAF 125/375 reads (33%) | catalogued as COSV54755463; called by muse, mutect2, varscan2
- DPP9 | c.1992C>T p.L664= (on ENST00000598800; = p.L693= on NM_139159.5) | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs374776149; called by muse, mutect2, varscan2
- EMP1 | c.291C>G p.L97= | Silent (SNP) | VAF 149/304 reads (49%) | catalogued as rs771449249, COSV56999197; called by muse, mutect2, varscan2
- EPHA3 | c.1497C>G p.L499= | Silent (SNP) | VAF 45/189 reads (24%) | catalogued as COSV60722268; called by muse, mutect2, varscan2
- EVI5L | c.927C>T p.L309= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs918272146, COSV99563205, COSV99563309; called by muse, mutect2
- FAM71D | c.417G>C p.L139= | Silent (SNP) | VAF 68/202 reads (34%) | catalogued as COSV100315144, COSV61296395; called by muse, mutect2, varscan2
- FBL | c.678C>A p.L226= | Silent (SNP) | VAF 47/96 reads (49%) | catalogued as COSV55683831; called by muse, mutect2, varscan2
- FCRL1 | c.942C>G p.L314= | Silent (SNP) | VAF 43/234 reads (18%) | catalogued as COSV100839855, COSV63826915; called by muse, mutect2, varscan2
- FNIP1 | c.732T>C p.P244= | Silent (SNP) | VAF 12/278 reads (4%) | catalogued as COSV100330455; called by muse, mutect2
- GNE | c.1215C>G p.L405= (on ENST00000396594 / NM_001128227.3; = p.L374= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 59/153 reads (39%) | catalogued as COSV100930158, COSV64952751; called by muse, mutect2, varscan2
- GPI | c.396C>T p.F132= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV62894720; called by muse, varscan2
- GRIA2 | c.1875G>A p.V625= | Silent (SNP) | VAF 10/306 reads (3%) | catalogued as COSV99644649; called by muse, mutect2
- GRID2 | c.2541C>T p.F847= | Silent (SNP) | VAF 92/235 reads (39%) | catalogued as COSV56251502; called by muse, mutect2, varscan2
- GRIPAP1 | c.216G>C p.L72= | Silent (SNP) | VAF 54/128 reads (42%) | catalogued as COSV64553115; called by muse, mutect2, varscan2
- GTF2IRD2 | c.264G>A p.V88= | Silent (SNP) | VAF 10/27 reads (37%) | called by mutect2, varscan2
- GTF2IRD2B | c.264G>A p.V88= | Silent (SNP) | VAF 35/318 reads (11%) | catalogued as COSV57032850; called by muse, mutect2, varscan2
- HCFC1 | c.5949C>T p.I1983= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs372071273, COSV60076491; ClinVar: likely benign; called by muse, mutect2, varscan2
- HIPK4 | c.1113C>T p.L371= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV52521966; called by muse, mutect2, varscan2
- HK1 | c.240C>T p.F80= | Silent (SNP) | VAF 68/231 reads (29%) | catalogued as rs1174484180, COSV53864502; called by muse, mutect2, varscan2
- IGSF9B | c.3162G>A p.A1054= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs764530495; called by muse, mutect2, varscan2
- IGSF9B | c.864G>A p.L288= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV58071604; called by muse, mutect2, varscan2
- IL36A | c.333G>A p.Q111= | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as COSV99382135; called by muse, mutect2
- ILK | c.960C>G p.L320= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV54991793; called by muse, mutect2, varscan2
- ITGAD | c.1689C>T p.I563= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV66758363, COSV66759678; called by muse, mutect2, varscan2
- KBTBD6 | c.1713C>T p.I571= | Silent (SNP) | VAF 157/393 reads (40%) | catalogued as COSV65271855; called by muse, mutect2, varscan2
- KIAA1217 | c.3816C>T p.G1272= | Silent (SNP) | VAF 50/96 reads (52%) | catalogued as COSV56821949; called by muse, mutect2, varscan2
- KNTC1 | c.2607C>G p.L869= | Silent (SNP) | VAF 230/425 reads (54%) | catalogued as COSV61083257; called by muse, mutect2, varscan2
- KRTAP15-1 | c.57G>A p.L19= | Silent (SNP) | VAF 46/158 reads (29%) | catalogued as rs779823461, COSV61877919; called by muse, mutect2, varscan2
- LIMD1 | c.1692C>T p.V564= | Silent (SNP) | VAF 51/185 reads (28%) | catalogued as COSV56269812; called by muse, mutect2, varscan2
- LMO1 | c.213C>T p.L71= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1440926072; called by muse, mutect2, varscan2
- LRRC66 | c.348C>T p.L116= | Silent (SNP) | VAF 162/375 reads (43%) | catalogued as COSV58636219; called by muse, mutect2, varscan2
- MDN1 | c.16629G>A p.P5543= | Silent (SNP) | VAF 86/330 reads (26%) | catalogued as rs778705375, COSV65528456; called by muse, mutect2, varscan2
- MEF2D | c.201C>T p.L67= | Silent (SNP) | VAF 124/503 reads (25%) | catalogued as COSV61730059; called by muse, mutect2, varscan2
- MEGF8 | c.4125C>T p.L1375= (on ENST00000251268 / NM_001271938.2; = p.L1308= on NM_001410.3) | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs751878364, COSV52098036; called by muse, mutect2, varscan2
- MIDEAS | c.3096G>A p.Q1032= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as rs538356336, COSV54098012; called by muse, mutect2, varscan2
- MMP15 | c.1161C>T p.F387= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV54681220; called by muse, mutect2, varscan2
- MRAP2 | c.617G>A p.*206= | Silent (SNP) | VAF 40/135 reads (30%) | catalogued as COSV100004819; called by muse, mutect2
- MTA2 | c.1782G>A p.Q594= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV53471590, COSV99545467; called by muse, mutect2, varscan2
- MYO10 | c.399C>T p.I133= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs752810171, COSV101549867, COSV72454448; called by muse, mutect2, varscan2
- MYO15A | c.5773C>T p.L1925= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV52760786, COSV52763461; called by muse, mutect2, varscan2
- MYO3A | c.4098G>A p.L1366= | Silent (SNP) | VAF 187/318 reads (59%) | catalogued as COSV56344737; called by muse, mutect2, varscan2
- NBPF1 | c.2196G>A p.E732= | Silent (SNP) | VAF 85/757 reads (11%) | catalogued as COSV55320948, COSV55328725; called by muse, mutect2, varscan2
- NEDD8 | c.219G>C p.L73= | Silent (SNP) | VAF 48/122 reads (39%) | catalogued as COSV51661527; called by muse, varscan2
- NFAT5 | c.2667G>A p.V889= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV100590658, COSV63031445; called by muse, mutect2, varscan2
- NHLH2 | c.345G>A p.K115= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV57202794; called by muse, mutect2, varscan2
- NLE1 | c.1005C>T p.L335= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs761450998, COSV62604882; called by muse, mutect2
- NOC4L | c.735G>A p.L245= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs745832393, COSV57959013; called by muse, mutect2, varscan2
- NRK | c.3304C>T p.L1102= | Silent (SNP) | VAF 62/151 reads (41%) | catalogued as COSV54604480; called by muse, mutect2, varscan2
- NT5DC2 | c.1041A>G p.E347= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV58741553; called by muse, mutect2, varscan2
- NTRK1 | c.2211C>T p.I737= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1041189894, COSV62327972; called by muse, mutect2, varscan2
- NUP58 | c.126C>T p.L42= | Silent (SNP) | VAF 58/140 reads (41%) | catalogued as COSV67751951; called by muse, mutect2, varscan2
- OBSCN | c.10863C>T p.V3621= | Silent (SNP) | VAF 37/225 reads (16%) | catalogued as COSV52815479; called by muse, mutect2, varscan2
- OR10J1 | c.873G>A p.L291= | Silent (SNP) | VAF 84/296 reads (28%) | catalogued as rs1442202058, COSV71129446; called by muse, mutect2, varscan2
- OR10J3 | c.186C>T p.F62= | Silent (SNP) | VAF 135/614 reads (22%) | catalogued as COSV59955408; called by muse, mutect2, varscan2
- OR14K1 | c.126C>T p.V42= | Silent (SNP) | VAF 84/352 reads (24%) | catalogued as COSV51722195, COSV99315387; called by muse, varscan2
- OR14K1 | c.243C>T p.L81= | Silent (SNP) | VAF 94/456 reads (21%) | catalogued as COSV51721836, COSV51722207; called by muse, varscan2
- OR1J1 | c.132C>T p.L44= | Silent (SNP) | VAF 105/209 reads (50%) | catalogued as COSV52239575; called by muse, mutect2, varscan2
- OR2T27 | c.624C>T p.L208= | Silent (SNP) | VAF 102/271 reads (38%) | catalogued as COSV61283285; called by muse, varscan2
- OR2T34 | c.150C>T p.L50= | Silent (SNP) | VAF 62/255 reads (24%) | catalogued as COSV60901701; called by mutect2, varscan2
- OR6M1 | c.906G>A p.V302= | Silent (SNP) | VAF 43/110 reads (39%) | catalogued as COSV58434573; called by muse, mutect2, varscan2
- OR8H2 | c.705G>A p.Q235= | Silent (SNP) | VAF 184/425 reads (43%) | catalogued as COSV57944435, COSV57946162; called by muse, mutect2, varscan2
- OSM | c.297C>T p.L99= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99304189; called by muse, mutect2, varscan2
- OTX2 | c.324G>A p.V108= (on ENST00000408990 / NM_172337.3; = p.V116= on NM_021728.4) | Silent (SNP) | VAF 62/160 reads (39%) | catalogued as COSV59767297; called by muse, mutect2, varscan2
- OVCH1 | c.276C>G p.L92= | Silent (SNP) | VAF 106/183 reads (58%) | catalogued as COSV55491302; called by muse, mutect2, varscan2
- PADI4 | c.1806C>T p.F602= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs373192530; called by muse, mutect2, varscan2
- PAPSS1 | c.1074G>A p.T358= | Silent (SNP) | VAF 102/247 reads (41%) | catalogued as rs368108957; called by muse, mutect2, varscan2
- PAX4 | c.873G>A p.L291= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV58390031; called by muse, mutect2, varscan2
- PCDHA11 | c.696C>G p.V232= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV56537044; called by muse, mutect2, varscan2
- PCDHGA8 | c.1509G>A p.S503= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs1438978424, COSV53922298; called by muse, mutect2, varscan2
- PDE7A | c.904C>T p.L302= (on ENST00000401827 / NM_001242318.3; = p.L276= on NM_002603.4) | Silent (SNP) | VAF 50/215 reads (23%) | catalogued as COSV101052649, COSV65154310; called by muse, mutect2, varscan2
- PDGFRB | c.885G>A p.E295= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as rs750127210, COSV55809080; called by muse, mutect2, varscan2
- PDS5A | c.3522G>A p.L1174= | Silent (SNP) | VAF 142/334 reads (43%) | catalogued as COSV57822441; called by muse, mutect2, varscan2
- PDZK1 | c.1357C>T p.L453= | Silent (SNP) | VAF 98/546 reads (18%) | catalogued as COSV58260242; called by muse, mutect2, varscan2
- PEX5 | c.369T>A p.L123= | Silent (SNP) | VAF 24/354 reads (7%) | catalogued as COSV99870979; called by muse, mutect2
- PIGV | c.666C>T p.F222= | Silent (SNP) | VAF 74/199 reads (37%) | catalogued as COSV99314957; called by muse, mutect2, varscan2
- PIK3CA | c.1002C>T p.L334= | Silent (SNP) | VAF 141/254 reads (56%) | catalogued as COSV55900595, COSV55922337; called by muse, mutect2, varscan2
- PLPP4 | c.507C>T p.T169= | Silent (SNP) | VAF 57/91 reads (63%) | catalogued as rs367745595; called by muse, mutect2, varscan2
- POM121L12 | c.861C>T p.V287= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1410909831, COSV68692613; called by muse, varscan2
- PPWD1 | c.285T>C p.H95= | Silent (SNP) | VAF 100/242 reads (41%) | catalogued as rs1561721674, COSV54335074; called by muse, mutect2, varscan2
- PRKCG | c.1731G>A p.S577= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as rs764921206, COSV54731764; called by muse, mutect2, varscan2
- PTCHD4 | c.2346C>T p.F782= | Silent (SNP) | VAF 101/383 reads (26%) | catalogued as COSV59794566; called by muse, mutect2, varscan2
- PTPN13 | c.6999C>G p.V2333= (on ENST00000411767 / NM_080683.3; = p.V2314= on NM_006264.3) | Silent (SNP) | VAF 62/138 reads (45%) | catalogued as COSV57415237; called by muse, mutect2, varscan2
- RAB5IF | c.135C>T p.I45= | Silent (SNP) | VAF 233/577 reads (40%) | catalogued as rs1228247895, COSV53412190; called by muse, mutect2, varscan2
- RANGRF | c.12G>A p.T4= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs375419554; called by muse, mutect2, varscan2
- REM1 | c.9C>G p.L3= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as COSV52429584, COSV52429636; called by muse, mutect2, varscan2
- RIN2 | c.1050G>A p.T350= (on ENST00000255006 / NM_001242581.1; = p.T301= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs756921810, COSV54792856, COSV54795703; called by muse, mutect2, varscan2
- RNF186 | c.555C>T p.I185= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV64296932; called by muse, mutect2, varscan2
- RPE65 | c.1350G>A p.L450= | Silent (SNP) | VAF 96/232 reads (41%) | catalogued as COSV52018014; called by muse, mutect2, varscan2
- RPS4X | c.516C>T p.F172= | Silent (SNP) | VAF 54/142 reads (38%) | catalogued as rs1411108534, COSV60182022; called by muse, mutect2
- RXFP1 | c.2238G>C p.L746= | Silent (SNP) | VAF 66/167 reads (40%) | catalogued as COSV57055020; called by muse, mutect2, varscan2
- RYR2 | c.12495C>G p.V4165= | Silent (SNP) | VAF 31/146 reads (21%) | catalogued as COSV63707256; called by muse, mutect2, varscan2
- SDK1 | c.1830G>A p.K610= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as rs369903581; called by muse, mutect2, varscan2
- SH3BP2 | c.954C>G p.S318= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV62555116; called by muse, mutect2, varscan2
- SIPA1L1 | c.3282T>C p.N1094= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV62172950; called by muse, mutect2, varscan2
- SLC38A6 | c.249G>A p.L83= | Silent (SNP) | VAF 218/562 reads (39%) | catalogued as COSV50785097; called by muse, mutect2, varscan2
- SLC4A1AP | c.972G>A p.K324= | Silent (SNP) | VAF 157/393 reads (40%) | catalogued as COSV58137317; called by muse, mutect2, varscan2
- SLC52A1 | c.390C>T p.V130= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as COSV54693665; called by muse, mutect2, varscan2
- SLC7A3 | c.867G>A p.V289= | Silent (SNP) | VAF 91/243 reads (37%) | catalogued as COSV53226573; called by muse, mutect2, varscan2
- SLC8B1 | c.288C>G p.L96= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as COSV52530068; called by muse, mutect2, varscan2
- SLFN11 | c.2514C>T p.L838= | Silent (SNP) | VAF 126/331 reads (38%) | catalogued as rs1249943054, COSV57700206; called by muse, mutect2, varscan2
- SMOX | c.702C>T p.I234= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV53867562; called by muse, mutect2, varscan2
- SPAG8 | c.843C>G p.L281= | Silent (SNP) | VAF 52/138 reads (38%) | catalogued as COSV52415482; called by muse, varscan2
- SPDYE3 | c.1482G>A p.P494= | Silent (SNP) | VAF 81/222 reads (36%) | catalogued as rs758269161, COSV60107012, COSV60107718; called by mutect2, varscan2
- SPEN | c.7872G>C p.R2624= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV101005259; called by muse, varscan2
- SPEN | c.7953G>A p.V2651= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV65366460; called by muse, varscan2
- SRGAP1 | c.1746C>G p.L582= | Silent (SNP) | VAF 126/222 reads (57%) | catalogued as rs1405082034, COSV61902047; called by muse, mutect2, varscan2
- STEAP1 | c.906G>C p.L302= | Silent (SNP) | VAF 80/183 reads (44%) | catalogued as COSV51882589; called by muse, mutect2, varscan2
- SYNE2 | c.13842G>C p.L4614= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV59965493; called by muse, varscan2
- SYNE2 | c.13884G>A p.L4628= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as COSV59965502; called by muse, varscan2
- SYTL5 | c.2157C>T p.L719= | Silent (SNP) | VAF 55/132 reads (42%) | catalogued as COSV52904581; called by muse, mutect2, varscan2
- TACR3 | c.255C>T p.I85= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV59203863; called by muse, mutect2, varscan2
- TAF1L | c.3552C>T p.L1184= | Silent (SNP) | VAF 135/321 reads (42%) | catalogued as COSV54267270; called by muse, mutect2, varscan2
- TMCC2 | c.2094C>T p.L698= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV58005880; called by muse, mutect2, varscan2
- TMEM72 | c.402G>A p.K134= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV67460326, COSV67461090; called by muse, mutect2, varscan2
- TOP2A | c.1914C>T p.F638= | Silent (SNP) | VAF 113/340 reads (33%) | catalogued as COSV70733610; called by muse, mutect2, varscan2
- TOR3A | c.808C>T p.L270= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV61680204; called by muse, mutect2, varscan2
- TRAV8-2 | c.120G>C p.L40= | Silent (SNP) | VAF 87/231 reads (38%) | called by muse, mutect2, varscan2
- TRIM17 | c.534G>A p.V178= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV52859547; called by muse, mutect2, varscan2
- TRPV2 | c.705C>T p.P235= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs780935485, COSV100641091, COSV58427561; called by muse, mutect2, varscan2
- TRRAP | c.8631G>A p.P2877= (on ENST00000359863 / NM_001244580.1; = p.P2859= on NM_003496.3) | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs770003844, COSV62846787; called by muse, mutect2, varscan2
- TRRAP | c.10401C>T p.F3467= (on ENST00000359863 / NM_001244580.1; = p.F3438= on NM_003496.3) | Silent (SNP) | VAF 55/143 reads (38%) | catalogued as COSV62852286; called by muse, mutect2, varscan2
- TSHZ1 | c.2328G>A p.K776= (on ENST00000580243 / NM_001308210.2; = p.K731= on NM_005786.6) | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV59015362; called by muse, mutect2, varscan2
- TTC38 | c.433C>T p.L145= | Silent (SNP) | VAF 100/235 reads (43%) | catalogued as COSV66844943; called by muse, mutect2, varscan2
- TUBGCP3 | c.847C>T p.L283= | Silent (SNP) | VAF 59/132 reads (45%) | catalogued as COSV56190622; called by muse, mutect2, varscan2
- TUT7 | c.1755G>A p.L585= | Silent (SNP) | VAF 97/238 reads (41%) | catalogued as COSV52898175; called by muse, mutect2, varscan2
- USB1 | c.627C>G p.L209= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV54683953; called by muse, mutect2, varscan2
- USP10 | c.2067C>T p.F689= | Silent (SNP) | VAF 106/252 reads (42%) | catalogued as rs769195477, COSV54751984; called by muse, mutect2, varscan2
- VANGL1 | c.1071G>A p.R357= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV100049210; called by muse, mutect2
- WDR33 | c.1170C>G p.L390= | Silent (SNP) | VAF 59/141 reads (42%) | catalogued as COSV59254528; called by muse, mutect2, varscan2
- WDR93 | c.633C>T p.L211= | Silent (SNP) | VAF 52/144 reads (36%) | catalogued as COSV51532412; called by muse, mutect2, varscan2
- YAE1 | c.363G>A p.L121= | Silent (SNP) | VAF 97/270 reads (36%) | catalogued as COSV56233599; called by muse, mutect2, varscan2
- ZFR | c.153G>C p.S51= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV54056926, COSV54057898; called by muse, mutect2, varscan2
- ZNF16 | c.1176G>A p.L392= | Silent (SNP) | VAF 102/211 reads (48%) | catalogued as COSV52765188, COSV99429598; called by muse, mutect2, varscan2
- ZNF441 | c.279G>A p.V93= | Silent (SNP) | VAF 65/157 reads (41%) | catalogued as COSV63540669; called by muse, mutect2, varscan2
- C12orf57 | c.*1G>C | 3'UTR (SNP) | VAF 15/30 reads (50%) | catalogued as COSV99980767; called by muse, mutect2, varscan2
- C3P1 | n.2983C>T | RNA (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- GALNT2 | c.*1G>C | 3'UTR (SNP) | VAF 18/43 reads (42%) | catalogued as COSV100795785; called by muse, mutect2, varscan2
- H2BP2 | chr1:143876196 C>G | 3'Flank (SNP) | VAF 41/221 reads (19%) | called by muse, mutect2, varscan2
- LARP6 | c.200+2246C>T | Intron (SNP) | VAF 101/264 reads (38%) | catalogued as rs1422912612, COSV54581931; called by muse, mutect2, varscan2
- MAGEC3 | c.1124-230C>G | Intron (SNP) | VAF 89/214 reads (42%) | catalogued as COSV100025061, COSV100025510; called by muse, mutect2, varscan2
- MKX | c.*1G>A | 3'UTR (SNP) | VAF 87/292 reads (30%) | catalogued as COSV101008788; called by muse, mutect2, varscan2
- NBPF7 | n.357G>C | RNA (SNP) | VAF 136/330 reads (41%) | called by muse, mutect2, varscan2
- PUS3 | c.-1C>G | 5'UTR (SNP) | VAF 144/375 reads (38%) | catalogued as COSV99916956; called by muse, mutect2, varscan2
- SMARCB1 | c.363-2336G>C | Intron (SNP) | VAF 36/80 reads (45%) | catalogued as COSV54095475; called by muse, mutect2, varscan2
- SUGP1 | c.539-140G>A | Intron (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99895150; called by muse, mutect2
